Somatic mutation profile of tumor specimen TCGA-ER-A194-01A (aliquot TCGA-ER-A194-01A-11D-A197-08) from TCGA case TCGA-ER-A194, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 77.4 years (28,253 days).
Specimen TCGA-ER-A194-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 992c27ea-742a-4019-9e56-a879aaadb0c2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ER-A194-10A (Blood Derived Normal), aliquot TCGA-ER-A194-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/18b534ec-8ff1-4d6d-95cb-1df2ced7badb

The open-access MAF lists 1,627 somatic variants for this specimen: 1,073 protein-altering or splice-affecting, 525 silent, 29 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 985, Silent 525, Nonsense Mutation 58, Splice Region 14, RNA 12, Intron 11, Splice Site 11, Frame Shift Del 5, 5'Flank 2, 3'UTR 2, 3'Flank 1, 5'UTR 1.

Variants (750 of 1,627; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA2 | c.9076C>T p.Q3026* | Nonsense Mutation (SNP) | VAF 8/38 reads (21%) | catalogued as rs80359159, CM014522, COSV66459364; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CRNKL1 | c.383C>T p.S128F | Missense Mutation (SNP) | VAF 33/96 reads (34%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1057519885, COSV55618331; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- HRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 10/42 reads (24%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.251); catalogued as rs104894226, CM053285, COSV54237021, COSV54237051; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- HRAS | c.37G>A p.G13S | Missense Mutation (SNP) | VAF 10/42 reads (24%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.383); catalogued as rs104894228, CM060018, COSV54236651, COSV54236730, COSV54241641; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NF1 | c.2530C>T p.L844F | Missense Mutation (SNP) | VAF 25/38 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs199474785, CM002379, COSV62197747; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PCED1B | c.1028C>T p.S343F | Missense Mutation (SNP) | VAF 51/174 reads (29%) | hotspot (GDC flag); SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs757280610, COSV71394886, COSV71395186; called by muse, mutect2, varscan2
- RBP4 | c.353G>A p.G118E | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1554887443, COSV65160553; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TMEM200C | c.55C>T p.R19C | Missense Mutation (SNP) | VAF 9/33 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV67309264, COSV67309384; called by muse, mutect2, varscan2
- TMPRSS3 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373058706, CM124935, CM124936; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA4 | c.3832G>A p.E1278K | Missense Mutation (SNP) | VAF 42/151 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV64676168; called by muse, mutect2, varscan2
- ABCB1 | c.2714G>A p.R905Q | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774299788, COSV55958979; called by muse, mutect2, varscan2
- ABCB1 | c.1738C>T p.R580W | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs200224345, COSV55958989; called by muse, mutect2, varscan2
- ABI3BP | c.1780G>A p.E594K | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.72); PolyPhen benign (0.023); catalogued as rs202185024, COSV52541411; called by muse, mutect2, varscan2
- AC098582.1 | c.526C>T p.P176S | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV52020408; called by muse, mutect2, varscan2
- ACAA2 | c.557C>T p.S186L | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs762428287, COSV53271791; called by muse, mutect2, varscan2
- ACKR1 | c.203C>T p.T68I | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV63673997; called by muse, mutect2, varscan2
- ACSM4 | c.801G>A p.W267* | Nonsense Mutation (SNP) | VAF 23/59 reads (39%) | catalogued as rs1411190053, COSV68068836, COSV68069144; called by muse, mutect2, varscan2
- ACTL7A | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.897); catalogued as COSV61777113; called by muse, mutect2, varscan2
- ACVR1 | c.49C>T p.P17S | Missense Mutation (SNP) | VAF 36/62 reads (58%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); catalogued as COSV55121469; called by muse, mutect2, varscan2
- ADAM2 | c.721G>A p.G241R | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs771578922, COSV55866194; called by muse, mutect2, varscan2
- ADAM23 | c.1688C>T p.A563V | Missense Mutation (SNP) | VAF 76/140 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.279); catalogued as COSV52224513; called by muse, mutect2, varscan2
- ADAMTS13 | c.3010C>T p.Q1004* | Nonsense Mutation (SNP) | VAF 11/26 reads (42%) | catalogued as COSV63022528; called by muse, mutect2
- ADAMTS16 | c.2572C>T p.P858S | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.216); catalogued as COSV57001119; called by muse, mutect2, varscan2
- ADAMTS2 | c.1248G>A p.M416I | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.218); catalogued as COSV51093411; called by muse, mutect2
- ADD1 | c.1060C>T p.R354C | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs145933934, COSV53272467; called by mutect2, varscan2
- ADGRL2 | c.1515G>A p.M505I | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV54680344; called by muse, mutect2, varscan2
- ADGRV1 | c.4444G>A p.D1482N | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1331697643, COSV67991910; called by muse, mutect2, varscan2
- ADGRV1 | c.4664C>T p.S1555L | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.877); catalogued as rs762055707, COSV101316026, COSV67979966; called by muse, mutect2, varscan2
- ADGRV1 | c.6353G>A p.G2118E | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67991914; called by muse, mutect2, varscan2
- ADGRV1 | c.10247G>A p.G3416E | Missense Mutation (SNP) | VAF 71/161 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.048); catalogued as rs1455003943, COSV67979348; called by muse, mutect2, varscan2
- ADGRV1 | c.10601C>T p.S3534L | Missense Mutation (SNP) | VAF 81/456 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs778374104, COSV67982263; called by muse, mutect2, varscan2
- AGAP3 | c.988A>G p.K330E (on ENST00000622464; = p.K366E on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.164); catalogued as COSV58995635; called by muse, mutect2, varscan2
- AGBL5 | c.1523G>A p.G508E | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59935633; called by muse, mutect2, varscan2
- AGRN | c.1666C>T p.P556S | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs768688446, COSV65070993, COSV65071530; called by muse, mutect2, varscan2
- AGT | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as rs781549278, COSV64183713; called by muse, mutect2, varscan2
- AHNAK2 | c.14854C>T p.P4952S | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.46); PolyPhen benign (0.011); catalogued as rs866378082, COSV60924488; called by muse, mutect2, varscan2
- AIMP1 | c.590T>C p.V197A | Missense Mutation (SNP) | VAF 49/129 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as COSV63639292; called by muse, mutect2, varscan2
- AKR1D1 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.17); catalogued as COSV54338891, COSV54339447; called by muse, mutect2, varscan2
- ALDH1B1 | c.1210G>A p.G404S | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.078); catalogued as rs1367763771, COSV66620367; called by muse, mutect2, varscan2
- ALK | c.2730G>A p.M910I | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.017); catalogued as rs867621462, COSV66582907; called by muse, mutect2, varscan2
- ALLC | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.765); catalogued as COSV52997192; called by muse, mutect2, varscan2
- AMHR2 | c.1318T>C p.Y440H | Missense Mutation (SNP) | VAF 71/247 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57686546; called by muse, mutect2, varscan2
- ANK3 | c.2545G>A p.D849N | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.863); catalogued as COSV55073287; called by muse, mutect2, varscan2
- ANK3 | c.1234C>T p.R412* | Nonsense Mutation (SNP) | VAF 12/43 reads (28%) | catalogued as COSV55073307; called by muse, mutect2, varscan2
- ANKRD34B | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); catalogued as COSV58614322; called by muse, mutect2, varscan2
- ANKRD34B | c.434G>A p.G145E | Missense Mutation (SNP) | VAF 49/144 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as rs750174676, COSV58614326; called by muse, mutect2, varscan2
- ANKRD35 | c.1519G>A p.D507N | Missense Mutation (SNP) | VAF 45/174 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV62911192; called by muse, mutect2, varscan2
- ANO2 | c.1108C>T p.L370F (on ENST00000356134 / NM_001278597.3; = p.L374F on NM_001278596.3) | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100502216, COSV59035951; called by muse, mutect2, varscan2
- ANXA10 | c.593T>G p.I198S | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.305); catalogued as COSV63739821; called by muse, mutect2, varscan2
- AOX1 | c.2332C>T p.P778S | Missense Mutation (SNP) | VAF 63/91 reads (69%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.692); catalogued as COSV65983158; called by muse, mutect2, varscan2
- AP002748.5 | c.1249C>T p.R417W | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs752299442, COSV59150788; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AP1G1 | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0.018); catalogued as rs1254154362, COSV55488869; called by muse, mutect2, varscan2
- APBA2 | c.1136C>T p.S379F | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67105393; called by muse, mutect2, varscan2
- APBB1 | c.955-1G>A p.X319_splice | Splice Site (SNP) | VAF 17/54 reads (31%) | catalogued as COSV54979352; called by muse, mutect2, varscan2
- APBB1 | c.862C>T p.P288S | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.099); catalogued as COSV54973401, COSV54979369; called by muse, mutect2, varscan2
- APOB | c.6534G>A p.M2178I | Missense Mutation (SNP) | VAF 82/376 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs1318574646, COSV51946033; called by muse, mutect2, varscan2
- APOBR | c.3025C>T p.R1009C (on ENST00000431282; = p.R1018C on NM_018690.4) | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.136); catalogued as rs528190355, COSV60489033; called by muse, mutect2, varscan2
- AQP2 | c.13C>T p.R5C | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs772585705, COSV52232066; called by muse, mutect2, varscan2
- ARAP2 | c.4930C>T p.P1644S | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT tolerated (0.88); PolyPhen benign (0.015); catalogued as rs752752978, COSV58290144; called by muse, mutect2, varscan2
- ARAP2 | c.2226G>A p.M742I | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); catalogued as rs1276238311, COSV58290149; called by muse, mutect2, varscan2
- ARFGEF2 | c.983C>T p.P328L | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV100904063, COSV64214145; called by muse, mutect2, varscan2
- ARFGEF2 | c.5080C>T p.L1694F | Missense Mutation (SNP) | VAF 50/245 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.601); catalogued as rs375184784; called by muse, mutect2, varscan2
- ARHGAP19 | c.1480C>T p.L494F | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.001); catalogued as COSV100363247, COSV57394857; called by muse, mutect2, varscan2
- ARHGEF15 | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.11); catalogued as rs1169087712, COSV62725954; called by muse, mutect2, varscan2
- ARHGEF4 | c.385G>A p.G129R | Missense Mutation (SNP) | VAF 47/86 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs149091381; called by muse, mutect2, varscan2
- ARID1A | c.2128C>T p.R710C | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs935971471, COSV61371767; called by muse, mutect2, varscan2
- ARID1A | c.2605G>A p.G869S | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV61384803; called by muse, mutect2, varscan2
- ARL6IP5 | c.325A>T p.S109C | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV56235466; called by muse, mutect2, varscan2
- ARMC4 | c.2341G>A p.G781R | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59456614; called by muse, mutect2, varscan2
- ARMC4 | c.572C>T p.S191L | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV53465549; called by muse, mutect2, varscan2
- ARRDC1 | c.758C>T p.P253L | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.265); catalogued as rs773443665, COSV58379428; called by muse, mutect2, varscan2
- ARSJ | c.1606C>T p.P536S | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV59539174; called by muse, mutect2, varscan2
- ASAH2 | c.742G>A p.G248R | Missense Mutation (SNP) | VAF 120/406 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100269759; called by muse, mutect2, varscan2
- ASPM | c.1416T>A p.F472L | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV54135309; called by muse, mutect2, varscan2
- ASPSCR1 | c.1406-1G>A p.X469_splice | Splice Site (SNP) | VAF 20/42 reads (48%) | catalogued as COSV100142301; called by muse, mutect2, varscan2
- ASPSCR1 | c.1406G>A p.G469D | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as COSV100142303; called by muse, mutect2, varscan2
- ATP10B | c.1621G>A p.E541K | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100513825; called by muse, mutect2, varscan2
- ATP1A3 | c.1538C>T p.A513V (on ENST00000545399 / NM_001256214.2; = p.A500V on NM_152296.5) | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57484790; called by muse, mutect2, varscan2
- ATP1B2 | c.695G>A p.G232D | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1363370341, COSV51516242; called by muse, mutect2, varscan2
- ATP2B1 | c.1052A>C p.K351T | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.287); catalogued as COSV53811140; called by muse, mutect2, varscan2
- ATP2B2 | c.2053G>A p.E685K (on ENST00000352432; = p.E651K on NM_001683.5) | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.093); catalogued as rs752661102, COSV59493351; called by muse, mutect2, varscan2
- ATP2C2 | c.1334C>T p.A445V | Missense Mutation (SNP) | VAF 67/166 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs370258691; called by muse, mutect2, varscan2
- ATR | c.7334C>T p.P2445L | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV63389732; called by muse, mutect2, varscan2
- ATR | c.1010T>A p.L337H | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.781); catalogued as COSV63389740; called by muse, mutect2, varscan2
- B4GALNT3 | c.2944C>T p.H982Y | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.67); PolyPhen benign (0.009); catalogued as rs747041543, COSV56756283; called by muse, mutect2, varscan2
- BAHCC1 | c.6512C>T p.P2171L | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1555659121, COSV57031188; called by muse, mutect2
- BAIAP2L1 | c.758C>T p.P253L | Missense Mutation (SNP) | VAF 50/168 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50058618; called by muse, mutect2, varscan2
- BANK1 | c.2326G>A p.E776K | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.641); catalogued as COSV59839694; called by muse, mutect2, varscan2
- BBS4 | c.299G>A p.S100N | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs376206327; called by muse, mutect2, varscan2
- BICD2 | c.1943C>T p.T648I | Missense Mutation (SNP) | VAF 59/200 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100793929; called by muse, mutect2, varscan2
- BMP10 | c.29C>T p.A10V | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV54896432; called by muse, mutect2
- BRD3 | c.1960G>A p.A654T | Missense Mutation (SNP) | VAF 45/158 reads (28%) | SIFT tolerated (0.96); PolyPhen benign (0.138); catalogued as COSV57705510; called by muse, mutect2, varscan2
- BRINP2 | c.1111C>T p.R371C | Missense Mutation (SNP) | VAF 49/180 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as rs759275578, COSV64178261; called by muse, mutect2, varscan2
- BRINP3 | c.2089G>A p.D697N | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.269); catalogued as rs1172739869, COSV66535014; called by muse, mutect2, varscan2
- BRINP3 | c.683C>T p.S228F | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV66535021; called by muse, mutect2, varscan2
- BSND | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.345); catalogued as COSV64871159; called by muse, mutect2, varscan2
- BSPRY | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.081); catalogued as rs570967595, COSV65243275; called by muse, mutect2, varscan2
- C12orf40 | c.283A>C p.M95L | Missense Mutation (SNP) | VAF 41/134 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV61136001; called by muse, mutect2, varscan2
- C1QTNF9 | c.643C>T p.P215S | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59657760; called by muse, mutect2, varscan2
- C1QTNF9B | c.643C>T p.P215S | Missense Mutation (SNP) | VAF 29/154 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65944446; called by muse, mutect2, varscan2
- C1R | c.487C>T p.R163W (on ENST00000536053 / NM_001354346.2; = p.R149W on NM_001733.7) | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.72); catalogued as rs373462345; called by muse, mutect2, varscan2
- C3 | c.3412G>A p.E1138K | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs781541367, COSV55569106; called by muse, mutect2, varscan2
- C3 | c.3130G>A p.G1044R | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.066); catalogued as COSV55578380, COSV55581347; called by muse, mutect2, varscan2
- C3orf20 | c.2669G>A p.R890K | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0.01); catalogued as COSV53787960, COSV99514641; called by muse, mutect2, varscan2
- C4B | c.3874C>T p.Q1292* | Nonsense Mutation (SNP) | VAF 37/181 reads (20%) | catalogued as rs762904292, COSV70313606; called by muse, mutect2, varscan2
- C6 | c.2155C>T p.Q719* | Nonsense Mutation (SNP) | VAF 17/50 reads (34%) | catalogued as COSV54715083, COSV99667057; called by muse, mutect2, varscan2
- C6 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs267600638, COSV54704649; called by muse, mutect2, varscan2
- C7 | c.1478G>A p.G493E | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.62); PolyPhen benign (0.011); catalogued as COSV100496749, COSV57473533; called by muse, mutect2, varscan2
- C7orf31 | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV52219267; called by muse, mutect2, varscan2
- C8B | c.1249G>A p.D417N | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV64777452; called by muse, mutect2, varscan2
- CA4 | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 38/69 reads (55%) | SIFT tolerated (0.22); PolyPhen benign (0.073); catalogued as COSV56282216; called by muse, mutect2, varscan2
- CACNA2D3 | c.381G>A p.Q127= | Splice Region (SNP) | VAF 4/18 reads (22%) | catalogued as COSV55540559; called by muse, mutect2
- CADM3 | c.1174G>A p.D392N (on ENST00000368125 / NM_001127173.3; = p.D426N on NM_021189.5) | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs772723270, COSV63673993; called by muse, mutect2, varscan2
- CADPS2 | c.2889G>A p.K963= | Splice Region (SNP) | VAF 19/62 reads (31%) | catalogued as COSV57377356; called by muse, mutect2, varscan2
- CAGE1 | c.1399G>A p.A467T (on ENST00000512086; = p.A331T on NM_205864.3) | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV57080270; called by muse, mutect2, varscan2
- CAMK1G | c.1132G>A p.G378S | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0); catalogued as COSV50524493; called by muse, mutect2, varscan2
- CAMK4 | c.91G>A p.D31N | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.537); catalogued as COSV56678900; called by muse, mutect2, varscan2
- CAPN5 | c.1535C>T p.P512L (on ENST00000456580; = p.P472L on NM_004055.5) | Missense Mutation (SNP) | VAF 39/191 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53690263; called by muse, mutect2, varscan2
- CAPN7 | c.673C>T p.P225S | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53779947; called by muse, mutect2, varscan2
- CAPS2 | c.1181G>A p.R394Q | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as rs373505414, COSV60824815; called by muse, mutect2, varscan2
- CASK | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 24/36 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs1310982151, COSV59363268; called by muse, mutect2, varscan2
- CASP1 | c.340C>T p.P114S (on ENST00000436863 / NM_033292.4; = p.P93S on NM_001223.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV62056252; called by muse, mutect2, varscan2
- CBLN4 | c.353G>A p.G118E | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50353837; called by muse, mutect2, varscan2
- CBY1 | c.43C>T p.P15S | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.886); catalogued as rs763053636, COSV53264620; called by muse, mutect2, varscan2
- CCDC130 | c.1031C>T p.P344L | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.085); catalogued as COSV50005088; called by muse, mutect2, varscan2
- CCDC178 | c.254G>A p.S85N | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55788663; called by muse, mutect2, varscan2
- CCDC60 | c.240A>T p.K80N | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV59548102; called by muse, mutect2, varscan2
- CCDC70 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.062); catalogued as rs761208113, COSV54430760, COSV99665367; called by muse, mutect2
- CCK | c.146G>A p.R49K | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as COSV58184237; called by muse, mutect2, varscan2
- CCNA1 | c.305C>G p.T102R | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.063); catalogued as COSV55223206; called by muse, mutect2, varscan2
- CCNJL | c.1285C>T p.P429S | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.851); catalogued as COSV57446087; called by muse, varscan2
- CCNJL | c.1252G>A p.G418R | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.172); catalogued as rs750482616, COSV57446099; called by muse, varscan2
- CD300LF | c.110C>T p.T37I | Missense Mutation (SNP) | VAF 90/168 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.4); catalogued as rs545949485, COSV56898235; called by muse, mutect2, varscan2
- CDC42 | c.194A>T p.D65V | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV59663131; called by muse, mutect2, varscan2
- CDC42BPG | c.2020G>A p.E674K | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.98); catalogued as COSV61348528; called by muse, mutect2, varscan2
- CDC42EP4 | c.871C>T p.P291S | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT tolerated (0.16); PolyPhen benign (0.321); catalogued as COSV59963767; called by muse, mutect2, varscan2
- CDCP1 | c.425C>T p.S142F | Missense Mutation (SNP) | VAF 51/209 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV56107160; called by muse, mutect2, varscan2
- CDH12 | c.2122G>A p.E708K | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.62); PolyPhen benign (0.096); catalogued as COSV101202212, COSV66432076; called by muse, mutect2, varscan2
- CDH17 | c.1487G>A p.S496N | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.173); catalogued as COSV50335743; called by muse, varscan2
- CDH17 | c.1468C>T p.H490Y | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.447); catalogued as COSV50335809; called by muse, varscan2
- CDH20 | c.2062G>A p.E688K | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT tolerated (0.82); PolyPhen possibly damaging (0.777); catalogued as COSV53009040; called by muse, mutect2, varscan2
- CDH6 | c.740G>A p.G247E | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54074558; called by muse, mutect2, varscan2
- CDH6 | c.847C>T p.P283S | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.207); catalogued as COSV54075441; called by muse, mutect2, varscan2
- CDH6 | c.980G>A p.G327E | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV54070089; called by muse, mutect2, varscan2
- CDH9 | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 81/165 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs776212558, COSV50264628; called by muse, mutect2, varscan2
- CDHR2 | c.1906G>A p.D636N | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.56); PolyPhen benign (0.046); catalogued as rs1379475217, COSV56142917; called by muse, mutect2, varscan2
- CEMIP | c.1413G>A p.G471= | Splice Region (SNP) | VAF 23/93 reads (25%) | catalogued as COSV54997747; called by muse, mutect2, varscan2
- CENPF | c.1402C>T p.Q468* | Nonsense Mutation (SNP) | VAF 16/45 reads (36%) | catalogued as rs1416716780, COSV65277541; called by muse, mutect2, varscan2
- CEP131 | c.2587G>A p.E863K (on ENST00000269392 / NM_001319228.2; = p.E860K on NM_014984.4) | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.79); catalogued as COSV53955180; called by muse, mutect2
- CEP43 | c.445C>T p.L149F | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as COSV62761368; called by muse, mutect2
- CEP85 | c.83C>T p.S28F | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.9); PolyPhen benign (0.003); catalogued as COSV53330927; called by muse, mutect2, varscan2
- CERT1 | c.1568C>T p.S523F (on ENST00000405807 / NM_001130105.1; = p.S395F on NM_005713.3) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.157); catalogued as rs1418180378, COSV54662764, COSV54663211; called by muse, mutect2, varscan2
- CFAP100 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs182563239, COSV61504071; called by mutect2, varscan2
- CFAP57 | c.973C>T p.P325S | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs756020796, COSV65265260; called by muse, mutect2, varscan2
- CFAP58 | c.1487C>T p.S496L | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); catalogued as COSV63833454; called by muse, mutect2, varscan2
- CFTR | c.484A>T p.K162* | Nonsense Mutation (SNP) | VAF 7/25 reads (28%) | catalogued as CM983541, COSV50079804; called by muse, mutect2, varscan2
- CHCHD6 | c.356C>T p.S119F | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.878); catalogued as COSV52066851; called by muse, mutect2, varscan2
- CHD1 | c.1591G>T p.G531* | Nonsense Mutation (SNP) | VAF 16/52 reads (31%) | catalogued as COSV52343337; called by muse, mutect2, varscan2
- CHD3 | c.3106C>T p.P1036S | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV57878491; called by muse, mutect2, varscan2
- CHD5 | c.3586G>A p.G1196S | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1253698140, COSV52421642; called by muse, mutect2, varscan2
- CHD7 | c.5945G>A p.G1982E | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM133771, COSV71113289; called by muse, mutect2, varscan2
- CHGB | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 89/178 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV66761394; called by muse, mutect2, varscan2
- CHIT1 | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs772910185, COSV55148726; called by muse, mutect2, varscan2
- CHRM3 | c.202G>A p.V68M | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV99697097; called by muse, mutect2, varscan2
- CHRM3 | c.203T>A p.V68E | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99697101; called by muse, mutect2, varscan2
- CHRM3 | c.1052C>T p.S351F | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV55097714; called by muse, mutect2, varscan2
- CHRNB3 | c.316C>T p.P106S | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51496741, COSV51497145; called by muse, mutect2, varscan2
- CHRNB3 | c.577A>T p.K193* | Nonsense Mutation (SNP) | VAF 35/89 reads (39%) | catalogued as COSV51496752; called by muse, mutect2, varscan2
- CILP2 | c.1109C>T p.S370L | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs768793354, COSV52278485; called by muse, mutect2, varscan2
- CILP2 | c.1628G>A p.R543Q | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.387); catalogued as COSV52273957, COSV52278501; called by muse, mutect2, varscan2
- CLEC14A | c.1000C>T p.P334S | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV60563778; called by muse, mutect2, varscan2
- CLEC18B | c.892C>T p.P298S | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100375584; called by muse, mutect2, varscan2
- CLEC5A | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as rs1197523757, COSV69397002; called by muse, mutect2, varscan2
- CLIC1 | c.599C>T p.P200L | Missense Mutation (SNP) | VAF 194/492 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65384273; called by muse, mutect2, varscan2
- CLTC | c.443T>A p.L148H | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52251027; called by muse, mutect2, varscan2
- CLVS1 | c.200G>A p.G67E | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.27); catalogued as COSV57970749; called by muse, mutect2, varscan2
- CMSS1 | c.440G>A p.R147K | Missense Mutation (SNP) | VAF 47/150 reads (31%) | SIFT tolerated (0.67); PolyPhen benign (0.193); catalogued as rs1222587769, COSV70440132; called by muse, mutect2, varscan2
- CMYA5 | c.2630C>T p.S877F | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV71408366; called by muse, mutect2, varscan2
- CNDP1 | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 42/132 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as rs766752633, COSV62594143; called by muse, mutect2, varscan2
- CNKSR2 | c.1252G>A p.E418K | Missense Mutation (SNP) | VAF 37/65 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as COSV54262817; called by muse, mutect2, varscan2
- CNTNAP4 | c.296G>A p.G99E | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); catalogued as rs769681418, COSV56671318; called by muse, mutect2, varscan2
- CNTNAP5 | c.107C>T p.S36F | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV70502006; called by muse, mutect2, varscan2
- COBL | c.2083C>T p.P695S | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.91); PolyPhen benign (0.018); catalogued as COSV54353873; called by muse, mutect2, varscan2
- COL17A1 | c.2630G>A p.G877E | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV62228544; called by muse, mutect2, varscan2
- COL27A1 | c.4753C>T p.P1585S | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.239); catalogued as COSV100620651; called by muse, mutect2, varscan2
- COL27A1 | c.4754C>T p.P1585L | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.083); catalogued as rs767818352, COSV100620652; called by muse, mutect2, varscan2
- COL4A1 | c.3515G>A p.G1172E | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65429565; called by muse, mutect2, varscan2
- COL4A1 | c.896G>A p.G299E | Missense Mutation (SNP) | VAF 35/147 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65428319, COSV65429570; called by muse, mutect2, varscan2
- COL4A2 | c.389G>A p.G130E | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64628472; called by muse, mutect2, varscan2
- COL4A5 | c.1765C>T p.P589S | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.45); PolyPhen benign (0.339); catalogued as COSV60367794; called by muse, mutect2
- COL4A5 | c.3989G>A p.G1330E | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60363218, COSV60367809; called by muse, mutect2, varscan2
- COL6A1 | c.790G>A p.D264N | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as rs530969007, COSV62614739; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPAMD8 | c.1777C>T p.H593Y (on ENST00000651564; = p.H546Y on NM_015692.5) | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.212); catalogued as COSV52237862; called by muse, mutect2, varscan2
- CPVL | c.652C>T p.H218Y | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs753700629, COSV55306226; called by muse, mutect2, varscan2
- CPXM2 | c.1402G>A p.D468N | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); catalogued as rs765333652, COSV53862220; called by muse, mutect2, varscan2
- CRAT | c.824C>T p.S275F | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58878388; called by muse, mutect2, varscan2
- CREB3L1 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV55832575; called by muse, mutect2, varscan2
- CRHR2 | c.1055G>A p.G352D | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776658451, COSV100529572; called by muse, varscan2
- CRHR2 | c.1054G>A p.G352S | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100529574; called by muse, mutect2, varscan2
- CSF2RA | c.1192G>A p.E398K | Missense Mutation (SNP) | VAF 54/207 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as COSV62625025; called by muse, mutect2, varscan2
- CSMD2 | c.8665G>A p.G2889R | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV53942759; called by muse, mutect2, varscan2
- CSMD2 | c.1360G>A p.E454K | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV53942780; called by muse, mutect2, varscan2
- CTDP1 | c.2470C>T p.Q824* | Nonsense Mutation (SNP) | VAF 106/302 reads (35%) | catalogued as COSV50006023, COSV50007266; called by muse, mutect2, varscan2
- CUBN | c.2513G>A p.G838E | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0.338); catalogued as rs1427812315, COSV64723154; called by muse, mutect2, varscan2
- CUEDC1 | c.337-1G>T p.X113_splice | Splice Site (SNP) | VAF 33/148 reads (22%) | catalogued as COSV100804617; called by muse, mutect2, varscan2
- CUL3 | c.1735G>A p.G579S | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.025); catalogued as COSV100024113, COSV52368296; called by muse, mutect2, varscan2
- CYB561 | c.565G>A p.G189S | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs77535447, COSV62540110; called by muse, mutect2
- CYB5A | c.227C>T p.S76F | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.871); catalogued as rs377196293; called by muse, mutect2, varscan2
- CYLC2 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.62); PolyPhen benign (0.01); catalogued as COSV66337696, COSV66337957, COSV66338899; called by muse, mutect2, varscan2
- CYP1A2 | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs375045680, COSV59659687; called by muse, mutect2, varscan2
- CYP26C1 | c.1219G>A p.V407M | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778973605, COSV53653487; called by muse, mutect2, varscan2
- CYP4F12 | c.841C>G p.Q281E | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0.038); catalogued as COSV61175560; called by muse, mutect2, varscan2
- DAG1 | c.1649C>T p.S550F | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.018); catalogued as rs1448902774, COSV58186241; called by muse, mutect2, varscan2
- DCAF12L2 | c.617C>T p.T206I | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.81); catalogued as COSV63582042; called by muse, mutect2, varscan2
- DCAF4L2 | c.196C>T p.P66S | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV60477508, COSV60477660; called by muse, mutect2, varscan2
- DCANP1 | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.162); catalogued as COSV72345886; called by muse, mutect2
- DDI1 | c.760C>T p.P254S | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56388121; called by muse, mutect2, varscan2
- DDX60L | c.164C>T p.S55L | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.14); catalogued as rs1262677852, COSV52719007; called by muse, mutect2, varscan2
- DENND2C | c.2065C>T p.L689F (on ENST00000393274 / NM_001256404.2; = p.L632F on NM_198459.4) | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV67923285; called by muse, mutect2, varscan2
- DENND3 | c.2692C>T p.L898F | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.669); catalogued as rs751636880, COSV52805092; called by muse, mutect2, varscan2
- DEUP1 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as COSV53215091; called by muse, mutect2
- DGKB | c.1609G>A p.G537R | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV51807248; called by muse, mutect2, varscan2
- DGKE | c.1010G>A p.R337Q | Missense Mutation (SNP) | VAF 61/98 reads (62%) | SIFT tolerated (0.31); PolyPhen benign (0.19); catalogued as rs368125102; called by muse, mutect2, varscan2
- DGKG | c.553C>T p.R185C | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs766010875, COSV53967626; called by muse, varscan2
- DGKI | c.395C>T p.S132L | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as rs770128558, COSV55967199; called by muse, mutect2, varscan2
- DHX34 | c.1639G>A p.E547K | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as rs1224034175, COSV60897126; called by muse, mutect2, varscan2
- DLL1 | c.1307C>T p.S436L | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as rs774614063, COSV64538197; called by muse, mutect2, varscan2
- DMD | c.10216A>T p.M3406L | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as COSV58936172; called by muse, mutect2, varscan2
- DNAAF1 | c.1525G>A p.E509K | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.792); catalogued as COSV57578352; called by muse, mutect2, varscan2
- DNAH11 | c.8017C>T p.P2673S | Missense Mutation (SNP) | VAF 40/139 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.077); catalogued as COSV60964919; called by muse, mutect2, varscan2
- DNAH17 | c.2399C>T p.S800L | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.47); catalogued as rs141150806; called by muse, mutect2, varscan2
- DNAH2 | c.3658C>T p.L1220F | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.461); catalogued as COSV66723589; called by muse, mutect2, varscan2
- DNAH3 | c.10391G>T p.W3464L | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); catalogued as COSV54517209, COSV54540103; called by muse, mutect2, varscan2
- DNAH3 | c.4948C>T p.Q1650* | Nonsense Mutation (SNP) | VAF 8/29 reads (28%) | catalogued as rs755876634, COSV54540124; called by muse, mutect2, varscan2
- DNAH3 | c.4202G>A p.R1401Q | Missense Mutation (SNP) | VAF 26/143 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs879199308, COSV99766366; called by muse, mutect2, varscan2
- DNAH5 | c.1853G>A p.R618Q | Missense Mutation (SNP) | VAF 25/40 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as rs757056449, CM150542, COSV54237241; called by muse, mutect2, varscan2
- DNAH9 | c.2521G>A p.D841N | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.881); catalogued as COSV52366634; called by muse, mutect2, varscan2
- DNAH9 | c.5513G>A p.G1838E | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52366644; called by muse, mutect2, varscan2
- DNAH9 | c.5776C>T p.R1926* | Nonsense Mutation (SNP) | VAF 11/40 reads (28%) | catalogued as rs750656556, COSV52338580, COSV52357296; called by muse, mutect2, varscan2
- DNAI2 | c.1375C>T p.R459W | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as rs1305647043, COSV56761400; called by muse, mutect2, varscan2
- DNAI4 | c.20C>T p.S7F | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.006); catalogued as COSV63085359; called by muse, mutect2, varscan2
- DNAJC6 | c.2144C>T p.P715L | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV54779434; called by muse, mutect2, varscan2
- DNPEP | c.890C>T p.A297V | Missense Mutation (SNP) | VAF 34/61 reads (56%) | SIFT tolerated (0.09); PolyPhen benign (0.168); catalogued as rs1302035149, COSV56110766, COSV99814995; called by muse, mutect2, varscan2
- DOCK11 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV52244754; called by muse, mutect2, varscan2
- DPEP3 | c.789G>A p.M263I | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.173); catalogued as COSV52052354; called by muse, mutect2, varscan2
- DQX1 | c.1406C>T p.P469L | Missense Mutation (SNP) | VAF 53/199 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV66353521; called by muse, mutect2, varscan2
- DSCAML1 | c.2901G>A p.W967* (on ENST00000321322; = p.W907* on NM_020693.4) | Nonsense Mutation (SNP) | VAF 9/20 reads (45%) | catalogued as COSV58398617; called by muse, mutect2, varscan2
- DSEL | c.829C>T p.H277Y | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.993); catalogued as rs1010284231, COSV59493594; called by muse, mutect2, varscan2
- DSG1 | c.2467C>T p.P823S | Missense Mutation (SNP) | VAF 37/138 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.104); catalogued as rs867317422, COSV57138094; called by muse, mutect2, varscan2
- DSG4 | c.51G>A p.V17= | Splice Region (SNP) | VAF 12/55 reads (22%) | catalogued as rs758293444, COSV57395245; called by muse, mutect2, varscan2
- DTX1 | c.1427G>A p.G476E | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55657097; called by muse, mutect2
- DUSP22 | c.173C>T p.S58L | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV60523881; called by muse, mutect2, varscan2
- DYRK3 | c.1184T>C p.F395S | Missense Mutation (SNP) | VAF 37/133 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV65607190; called by muse, mutect2, varscan2
- DZIP1 | c.2176G>A p.G726R (on ENST00000347108; = p.G707R on NM_014934.5) | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.386); catalogued as rs536467966, COSV61268314; called by muse, mutect2, varscan2
- ECPAS | c.4255G>A p.G1419S | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as COSV52204215; called by muse, mutect2, varscan2
- ECSIT | c.409C>T p.P137S | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52940244; called by muse, mutect2, varscan2
- EDC3 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV59341219; called by muse, mutect2, varscan2
- EFHB | c.1544G>A p.G515E | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs750482794, COSV55551668; called by muse, mutect2, varscan2
- EHBP1 | c.3199T>A p.F1067I | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV99859602; called by muse, mutect2, varscan2
- EIF2AK3 | c.401C>T p.S134F | Missense Mutation (SNP) | VAF 68/254 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100303251; called by muse, mutect2, varscan2
- EMILIN2 | c.410G>A p.R137Q | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.162); catalogued as rs147386217, COSV54421566; called by muse, mutect2, varscan2
- ENAM | c.191A>T p.N64I | Missense Mutation (SNP) | VAF 99/348 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV68536682; called by muse, mutect2, varscan2
- EPB41L1 | c.1990G>A p.G664R | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV52441985; called by muse, mutect2, varscan2
- EPHB6 | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.48); PolyPhen probably damaging (1); catalogued as rs754050538, COSV67417991; called by muse, mutect2, varscan2
- EPHB6 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (1); PolyPhen probably damaging (1); catalogued as COSV101235852; called by muse, mutect2, varscan2
- EPHB6 | c.2645C>T p.P882L | Missense Mutation (SNP) | VAF 66/312 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1381991149, COSV63892036, COSV63892959; called by muse, mutect2, varscan2
- EPPK1 | c.496G>A p.G166R | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as COSV73262143; called by muse, mutect2, varscan2
- ERBB3 | c.1594C>T p.H532Y | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.068); catalogued as COSV99915327; called by muse, mutect2, varscan2
- ERC2 | c.451C>T p.Q151* | Nonsense Mutation (SNP) | VAF 82/253 reads (32%) | catalogued as COSV55648655, COSV99891783; called by muse, varscan2
- ERCC4 | c.2303C>T p.S768F | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.877); catalogued as rs12928650; called by muse, mutect2, varscan2
- ERN1 | c.1709C>T p.S570F | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as COSV70500344; called by muse, mutect2
- EVA1C | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs770419820, COSV55825931; called by muse, mutect2, varscan2
- EVPL | c.4778G>A p.G1593E | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56908377, COSV56914165; called by muse, mutect2, varscan2
- EXD1 | c.547-1G>A p.X183_splice | Splice Site (SNP) | VAF 8/42 reads (19%) | catalogued as rs1229611134, COSV59255648; called by muse, mutect2, varscan2
- EXD3 | c.2624C>T p.P875L | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.024); catalogued as rs770410177, COSV59811199; called by muse, mutect2, varscan2
- EXOC2 | c.847C>T p.L283F | Missense Mutation (SNP) | VAF 31/238 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.088); catalogued as COSV57869717; called by muse, mutect2, varscan2
- EYA2 | c.437G>A p.G146E | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.642); catalogued as rs1349679130, COSV57948555, COSV57949079; called by muse, mutect2, varscan2
- EYA3 | c.553C>T p.P185S | Missense Mutation (SNP) | VAF 39/122 reads (32%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as COSV65817385; called by muse, mutect2, varscan2
- F11 | c.1771G>A p.G591S | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53002608; called by muse, mutect2, varscan2
- F5 | c.2978G>A p.G993E | Missense Mutation (SNP) | VAF 50/169 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.36); catalogued as rs1340945135, COSV63126454; called by muse, mutect2, varscan2
- F5 | c.1305C>A p.F435L | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV63126461; called by muse, mutect2, varscan2
- FAAH2 | c.1219C>T p.P407S | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.475); catalogued as rs762950159, COSV66510440; called by muse, mutect2, varscan2
- FAM120B | c.543T>G p.D181E | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53006891; called by muse, mutect2, varscan2
- FAM153B | c.735G>A p.K245= (on ENST00000253490; = p.K168= on NM_001265615.1) | Splice Region (SNP) | VAF 40/313 reads (13%) | catalogued as COSV53687720; called by muse, mutect2, varscan2
- FAM83C | c.2096G>A p.G699E | Missense Mutation (SNP) | VAF 28/160 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.203); catalogued as COSV65583974; called by muse, mutect2, varscan2
- FAT3 | c.404G>A p.G135E | Missense Mutation (SNP) | VAF 148/500 reads (30%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.99); catalogued as COSV53153357; called by muse, mutect2, varscan2
- FAT3 | c.13619G>A p.S4540N | Missense Mutation (SNP) | VAF 119/494 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV53153373; called by muse, mutect2, varscan2
- FAT4 | c.4775C>T p.P1592L | Missense Mutation (SNP) | VAF 42/143 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV67895319; called by muse, mutect2, varscan2
- FAT4 | c.11368G>A p.E3790K | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.164); catalogued as rs776516773, COSV58669787; called by muse, mutect2, varscan2
- FBN2 | c.3779C>T p.S1260L | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.977); catalogued as COSV52533871; called by muse, mutect2, varscan2
- FBN3 | c.7624T>A p.C2542S | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); catalogued as COSV54468265; called by muse, mutect2, varscan2
- FBXL7 | c.1072G>C p.A358P | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs746538228, COSV61650308, COSV61652729; called by muse, mutect2, varscan2
- FGFR3 | c.1000G>A p.G334S | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99599750; called by muse, mutect2, varscan2
- FHDC1 | c.989C>A p.A330E | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV52602004; called by muse, mutect2, varscan2
- FHIT | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV59314613; called by muse, mutect2, varscan2
- FKBP5 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 50/247 reads (20%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV61883174; called by muse, mutect2, varscan2
- FKTN | c.1006C>T p.Q336* | Nonsense Mutation (SNP) | VAF 10/25 reads (40%) | catalogued as COSV56311317; called by muse, mutect2, varscan2
- FLG2 | c.1558C>T p.Q520* | Nonsense Mutation (SNP) | VAF 68/226 reads (30%) | catalogued as COSV66171367; called by muse, mutect2, varscan2
- FLNB | c.3839G>A p.C1280Y | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.041); catalogued as COSV55889687; called by muse, mutect2, varscan2
- FLNC | c.6667G>A p.G2223R | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV57961379; called by muse, mutect2, varscan2
- FLRT2 | c.1786G>A p.D596N | Missense Mutation (SNP) | VAF 37/150 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58147316; called by muse, mutect2, varscan2
- FNDC1 | c.1661T>A p.M554K | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV51944576; called by muse, mutect2, varscan2
- FNDC1 | c.1781G>A p.R594K | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV51931708; called by muse, mutect2, varscan2
- FNDC1 | c.2855T>C p.V952A | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV51944594; called by muse, mutect2
- FNDC3A | c.983A>C p.E328A (on ENST00000492622 / NM_001079673.2; = p.E272A on NM_014923.5) | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.292); catalogued as COSV68134361; called by muse, mutect2, varscan2
- FNDC3A | c.1451C>T p.S484F (on ENST00000492622 / NM_001079673.2; = p.S428F on NM_014923.5) | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.577); catalogued as COSV68134368; called by muse, mutect2, varscan2
- FNDC7 | c.1765C>T p.Q589* | Nonsense Mutation (SNP) | VAF 21/96 reads (22%) | catalogued as COSV54756406; called by muse, mutect2, varscan2
- FOLH1 | c.616G>A p.G206R | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs397834560; called by muse, mutect2, varscan2
- FOLR1 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.82); PolyPhen benign (0.038); catalogued as COSV56616329; called by muse, mutect2, varscan2
- FOXD4L1 | c.208C>T p.P70S | Missense Mutation (SNP) | VAF 66/97 reads (68%) | SIFT tolerated (0.15); PolyPhen benign (0.125); catalogued as rs1383967327, COSV52075888; called by muse, mutect2, varscan2
- FPR3 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.3); catalogued as COSV59331298, COSV59332657; called by muse, mutect2, varscan2
- FREM2 | c.7652-1G>A p.X2551_splice | Splice Site (SNP) | VAF 12/47 reads (26%) | catalogued as COSV99745947; called by muse, mutect2, varscan2
- FREM2 | c.7652G>A p.G2551D | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99745949; called by muse, mutect2, varscan2
- FRK | c.1225A>G p.K409E | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.418); catalogued as rs766611219, COSV73384142; called by muse, mutect2, varscan2
- FRS3 | c.1064C>T p.P355L | Missense Mutation (SNP) | VAF 57/111 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as rs758107928, COSV52485924; called by muse, mutect2, varscan2
- FRYL | c.2806C>T p.L936F | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as COSV51956446; called by muse, mutect2, varscan2
- FRYL | c.914C>T p.S305L | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs750122952, COSV51956459, COSV99975994; called by muse, mutect2, varscan2
- FSTL5 | c.1264G>A p.D422N | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.873); catalogued as COSV60216744; called by muse, mutect2, varscan2
- FUT9 | c.529C>T p.P177S | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV56149609; called by muse, mutect2, varscan2
- G3BP2 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 41/156 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.672); catalogued as rs765465830, COSV62977156; called by muse, mutect2, varscan2
- GAB3 | c.1430G>A p.R477Q | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.205); catalogued as rs1488680307, COSV65819055; called by muse, mutect2
- GABBR1 | c.209A>G p.E70G | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.089); catalogued as COSV63543900; called by muse, mutect2, varscan2
- GABRA2 | c.1216G>A p.E406K | Missense Mutation (SNP) | VAF 69/243 reads (28%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.676); catalogued as COSV62917848; called by muse, mutect2, varscan2
- GABRP | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV54664574; called by muse, mutect2, varscan2
- GAD2 | c.923G>A p.G308E | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV52155465; called by muse, mutect2
- GALNT13 | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV67217413, COSV67220468; called by muse, mutect2, varscan2
- GALNT13 | c.808C>T p.P270S | Missense Mutation (SNP) | VAF 25/38 reads (66%) | SIFT tolerated (0.08); PolyPhen benign (0.445); catalogued as rs752238590, COSV67232341; called by muse, mutect2, varscan2
- GALNT17 | c.1198C>T p.R400C | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774457548, COSV61148627; called by muse, mutect2, varscan2
- GALNTL6 | c.1337C>T p.P446L | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs752183772, COSV72491581, COSV72492524; called by mutect2, varscan2
- GAPDH | c.43G>A p.G15R | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.415); catalogued as COSV99975324; called by muse, mutect2, varscan2
- GAPDH | c.44G>A p.G15E | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.953); catalogued as COSV99975328; called by muse, mutect2, varscan2
- GASK1B | c.1450G>A p.G484R | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1400754412, COSV56710657; called by muse, mutect2, varscan2
- GATA6 | c.1449G>A p.M483I | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as COSV52524369; called by muse, mutect2, varscan2
- GCK | c.686G>A p.G229D | Missense Mutation (SNP) | VAF 74/273 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM096861, CM096862, COSV60787612; called by muse, mutect2, varscan2
- GDAP1L1 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT tolerated (0.39); PolyPhen benign (0.039); catalogued as rs370507208; called by muse, mutect2, varscan2
- GDF5 | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 37/178 reads (21%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.797); catalogued as rs771940166, COSV65502724; called by muse, mutect2, varscan2
- GGA3 | c.300+1G>A p.X100_splice | Splice Site (SNP) | VAF 35/243 reads (14%) | catalogued as COSV99821817; called by muse, mutect2, varscan2
- GGA3 | c.300G>A p.K100= | Splice Region (SNP) | VAF 36/244 reads (15%) | catalogued as COSV99821818; called by muse, mutect2, varscan2
- GHSR | c.304C>T p.R102C | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53840859; called by muse, mutect2, varscan2
- GIGYF2 | c.1621C>T p.P541S | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65246708; called by muse, mutect2, varscan2
- GIMAP2 | c.883T>A p.C295S | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV56235990; called by muse, mutect2, varscan2
- GIMAP5 | c.529G>A p.V177M | Missense Mutation (SNP) | VAF 51/141 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as COSV57530271; called by muse, mutect2, varscan2
- GIMAP6 | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 66/236 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs866496608, COSV61032580; called by muse, mutect2, varscan2
- GIMAP7 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.71); catalogued as COSV57958911; called by muse, mutect2, varscan2
- GLG1 | c.1180C>T p.R394C | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV52668741; called by muse, mutect2, varscan2
- GLIS3 | c.1907G>A p.R636K | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.018); catalogued as COSV60933274; called by muse, mutect2, varscan2
- GNLY | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.043); catalogued as COSV55704312, COSV99809050; called by muse, mutect2
- GON4L | c.5692C>T p.H1898Y | Missense Mutation (SNP) | VAF 58/182 reads (32%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.099); catalogued as rs750319122, COSV55199832; called by muse, mutect2, varscan2
- GPC5 | c.514C>T p.P172S | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65588549; called by muse, mutect2, varscan2
- GPLD1 | c.1415C>T p.P472L | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57759812; called by muse, mutect2, varscan2
- GPR12 | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV67344584; called by muse, mutect2, varscan2
- GPR179 | c.695C>T p.P232L | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1173620024; called by muse, mutect2, varscan2
- GPRIN2 | c.248G>A p.R83Q | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782485720, COSV65400263, COSV65400709; called by muse, mutect2
- GPX6 | c.314G>A p.G105E | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV62658649; called by muse, mutect2, varscan2
- GRB10 | c.1771C>T p.R591* (on ENST00000398812; = p.R545* on NM_001001549.3) | Nonsense Mutation (SNP) | VAF 20/103 reads (19%) | catalogued as rs775842626, COSV60013275; called by muse, mutect2, varscan2
- GRIA1 | c.1052G>A p.G351E | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs267600496, COSV53616653; called by muse, mutect2, varscan2
- GRIN2A | c.1202C>T p.P401L | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs1489261681, COSV58032859, COSV58037182; ClinVar: not provided; called by muse, mutect2, varscan2
- GRIN2B | c.3871C>T p.Q1291* | Nonsense Mutation (SNP) | VAF 34/128 reads (27%) | catalogued as rs755348109, COSV74207092; called by muse, mutect2, varscan2
- GRIP2 | c.1469C>T p.S490F (on ENST00000619221; = p.S393F on NM_001080423.4) | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as COSV56123520; called by muse, mutect2, varscan2
- GRM7 | c.2035C>T p.R679W | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63159440; called by muse, mutect2, varscan2
- GRM8 | c.1946C>T p.S649F | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.14); catalogued as rs267601269, COSV58808223; called by muse, mutect2, varscan2
- GTF2IRD1 | c.1189C>T p.P397S | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs782523577, COSV56089918; called by muse, mutect2, varscan2
- GTF3C1 | c.4958C>T p.S1653F | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as rs775959954, COSV62243577; called by muse, mutect2, varscan2
- GTSF1L | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.946); catalogued as COSV65932671; called by muse, mutect2, varscan2
- GUCY1A1 | c.767C>T p.S256F | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.606); catalogued as rs556601718, COSV56649696; called by muse, mutect2, varscan2
- GYS2 | c.1507G>A p.G503R | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53926889; called by muse, mutect2, varscan2
- HBG2 | c.431C>T p.S144F | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.028); catalogued as COSV100400529; called by muse, mutect2, varscan2
- HCAR2 | c.584T>C p.L195P | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs200492929, COSV61025513; called by muse, mutect2, varscan2
- HCRTR2 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as rs766006062, COSV63793711, COSV99057010; called by muse, mutect2, varscan2
- HDAC9 | c.2065G>A p.E689K | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.186); catalogued as COSV67781348, COSV67783378; called by muse, mutect2, varscan2
- HDLBP | c.1397A>G p.K466R | Missense Mutation (SNP) | VAF 48/99 reads (48%) | SIFT tolerated (0.31); PolyPhen benign (0.118); catalogued as rs755620029, COSV60499416; called by muse, mutect2, varscan2
- HEATR5A | c.4880C>T p.S1627F | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.521); catalogued as COSV66343996; called by muse, mutect2, varscan2
- HECTD4 | c.5831C>T p.A1944V | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.998); catalogued as COSV66396891; called by muse, mutect2, varscan2
- HECW1 | c.4680G>T p.E1560D | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.651); catalogued as rs985918615, COSV67836753; called by muse, mutect2, varscan2
- HEG1 | c.3735C>T p.P1245= | Splice Region (SNP) | VAF 6/14 reads (43%) | catalogued as COSV60764357; called by muse, mutect2, varscan2
- HELZ2 | c.2221G>A p.E741K (on ENST00000467148 / NM_001037335.2; = p.E172K on NM_033405.3) | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.68); catalogued as rs114630740; called by muse, mutect2, varscan2
- HERC2 | c.1703C>T p.A568V | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs773865370, COSV55341357; called by muse, mutect2, varscan2
- HEXA | c.655C>T p.P219S | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51507905; called by muse, mutect2, varscan2
- HEXIM1 | c.374C>T p.S125F | Missense Mutation (SNP) | VAF 11/12 reads (92%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs202151146, COSV100203377; called by muse, varscan2
- HFM1 | c.2729T>C p.L910S | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54033947; called by muse, mutect2, varscan2
- HIVEP2 | c.6176C>T p.S2059L | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV50035811; called by muse, mutect2, varscan2
- HIVEP3 | c.253C>A p.P85T | Missense Mutation (SNP) | VAF 61/234 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV56020551; called by muse, mutect2, varscan2
- HS3ST1 | c.731C>T p.S244L | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.932); catalogued as rs769665525, COSV50023171; called by muse, mutect2
- HS6ST3 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.468); catalogued as COSV65015621; called by muse, mutect2, varscan2
- HSPA6 | c.1210G>A p.G404R | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100553774; called by muse, mutect2, varscan2
- HSPA6 | c.1211G>A p.G404E | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV100553778; called by muse, mutect2, varscan2
- HTR1F | c.483G>A p.W161* | Nonsense Mutation (SNP) | VAF 17/39 reads (44%) | catalogued as COSV60390849; called by muse, mutect2, varscan2
- HTR2C | c.577G>A p.G193R | Missense Mutation (SNP) | VAF 37/61 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52220158; called by muse, mutect2, varscan2
- HTRA1 | c.860C>T p.S287F | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV64564945; called by muse, mutect2, varscan2
- HTT | c.3112G>A p.V1038I | Missense Mutation (SNP) | VAF 47/147 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as rs987280795, COSV61866635; called by muse, mutect2, varscan2
- HYDIN | c.12482G>A p.G4161E | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV66638025; called by muse, mutect2, varscan2
- HYDIN | c.9353T>G p.V3118G | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV59265562; called by muse, mutect2, varscan2
- IBSP | c.376G>A p.G126R | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as rs1255607609, COSV56896717, COSV99883489; called by muse, mutect2, varscan2
- IGDCC4 | c.3731C>T p.S1244F | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.027); catalogued as COSV61538532; called by muse, mutect2, varscan2
- IGF2BP3 | c.941C>T p.P314L | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.028); catalogued as COSV51679888, COSV51690374; called by muse, mutect2, varscan2
- IGSF21 | c.940G>A p.D314N | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs377200558, COSV52133148, COSV52140264; called by muse, mutect2, varscan2
- IKBKE | c.667C>T p.P223S | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65626514; called by muse, mutect2, varscan2
- IL12B | c.127G>A p.G43R | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.921); catalogued as rs144020395; called by muse, mutect2, varscan2
- IL1B | c.359G>A p.R120Q | Missense Mutation (SNP) | VAF 48/93 reads (52%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs1028585391, COSV54522613; called by muse, mutect2, varscan2
- IL31RA | c.637G>A p.D213N | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV51683816; called by muse, mutect2, varscan2
- ING3 | c.898C>T p.R300* | Nonsense Mutation (SNP) | VAF 8/26 reads (31%) | catalogued as COSV59951845; called by muse, mutect2
- INPP5D | c.394C>T p.P132S (on ENST00000445964 / NM_001017915.3; = p.P131S on NM_005541.5) | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.46); PolyPhen benign (0.012); catalogued as COSV64039077; called by muse, mutect2, varscan2
- INPP5D | c.1387G>A p.E463K (on ENST00000445964 / NM_001017915.3; = p.E462K on NM_005541.5) | Missense Mutation (SNP) | VAF 46/79 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV64039081; called by muse, mutect2, varscan2
- INSL6 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0.011); catalogued as rs1381072524, COSV67563289; called by muse, mutect2, varscan2
- INSR | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 171/529 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57158933; called by muse, mutect2, varscan2
- INSRR | c.3214C>T p.R1072* | Nonsense Mutation (SNP) | VAF 30/109 reads (28%) | catalogued as rs201715497, COSV63871157; called by muse, mutect2, varscan2
- INTS1 | c.3583C>T p.P1195S | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765088052, COSV101248329, COSV67178926; called by muse, mutect2, varscan2
- INTS1 | c.313C>T p.P105S | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.092); catalogued as COSV67177216; called by muse, mutect2, varscan2
- INTS10 | c.442-2A>T p.X148_splice | Splice Site (SNP) | VAF 6/30 reads (20%) | catalogued as COSV67604758; called by muse, mutect2, varscan2
- IP6K3 | c.416C>T p.P139L | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.017); catalogued as rs770106812, COSV53389483; called by muse, mutect2, varscan2
- IQCN | c.143A>T p.E48V | Missense Mutation (SNP) | VAF 56/156 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.206); catalogued as COSV66576294; called by muse, mutect2, varscan2
- IRF5 | c.784C>T p.R262W | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.597); catalogued as rs746828797, COSV50859893; called by muse, mutect2
- ITGA10 | c.3242C>T p.S1081F | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV65198541; called by muse, mutect2, varscan2
- ITGA11 | c.1942G>A p.E648K | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); catalogued as rs769468685, COSV59880586; called by muse, mutect2, varscan2
- ITGA2B | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.148); catalogued as COSV52234154; called by muse, mutect2, varscan2
- ITGA4 | c.346A>T p.K116* | Nonsense Mutation (SNP) | VAF 26/48 reads (54%) | catalogued as COSV52002719, COSV52004840; called by muse, mutect2, varscan2
- ITGA5 | c.1053G>A p.M351I | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV53219742; called by muse, mutect2, varscan2
- ITGA9 | c.2558G>A p.G853E | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53249118; called by muse, mutect2, varscan2
- ITGAE | c.220C>T p.Q74* | Nonsense Mutation (SNP) | VAF 15/78 reads (19%) | catalogued as COSV53997739; called by muse, mutect2, varscan2
- ITIH3 | c.2207G>A p.R736K | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV69649785; called by muse, mutect2, varscan2
- ITPR1 | c.2263G>A p.E755K (on ENST00000354582; = p.E740K on NM_002222.7) | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.062); catalogued as COSV56996351; called by muse, mutect2
- IYD | c.340G>C p.E114Q | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.08); catalogued as rs757403233, COSV57601075, COSV57603059; called by muse, mutect2, varscan2
- JCAD | c.4043C>T p.P1348L | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.086); catalogued as rs1357049161, COSV64761041; called by muse, mutect2, varscan2
- KALRN | c.4726C>T p.R1576* | Nonsense Mutation (SNP) | VAF 31/100 reads (31%) | catalogued as rs201046827, COSV53775069; called by muse, mutect2, varscan2
- KALRN | c.5209G>A p.G1737S (on ENST00000360013 / NM_001024660.4; = p.G40S on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.792); catalogued as COSV52261776; called by muse, mutect2, varscan2
- KATNAL2 | c.550G>A p.G184S (on ENST00000356157 / NM_001353899.1; = p.G112S on NM_031303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.018); catalogued as COSV55304710; called by muse, mutect2, varscan2
- KAZN | c.2128G>A p.E710K | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.055); catalogued as COSV60455454; called by muse, mutect2, varscan2
- KBTBD12 | c.1114G>A p.A372T | Missense Mutation (SNP) | VAF 49/203 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV59681083; called by muse, mutect2, varscan2
- KCNA6 | c.739G>A p.G247S | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV54976765; called by muse, mutect2, varscan2
- KCNB1 | c.1522G>A p.E508K | Missense Mutation (SNP) | VAF 109/275 reads (40%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.186); catalogued as COSV65569076; called by muse, mutect2, varscan2
- KCNC2 | c.1760C>T p.S587F | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.212); catalogued as COSV54375444; called by muse, mutect2, varscan2
- KCNH5 | c.2620C>T p.R874C | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as rs754436628, COSV59753363; called by muse, mutect2, varscan2
- KCNH5 | c.1858G>A p.E620K | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.673); catalogued as COSV59751934; called by muse, mutect2, varscan2
- KCNH5 | c.438G>A p.W146* | Nonsense Mutation (SNP) | VAF 20/60 reads (33%) | catalogued as COSV59770706; called by muse, mutect2
- KCNH6 | c.262G>A p.G88R | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV59006294; called by muse, mutect2, varscan2
- KCNH7 | c.3539G>A p.G1180E | Missense Mutation (SNP) | VAF 30/49 reads (61%) | SIFT tolerated, low confidence (1); PolyPhen possibly damaging (0.693); catalogued as COSV59807457; called by muse, mutect2, varscan2
- KCNH8 | c.2548G>A p.E850K | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.021); catalogued as rs1020422412, COSV60457761; called by muse, mutect2, varscan2
- KCNJ10 | c.818G>A p.G273D | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.772); catalogued as COSV63634560; called by muse, mutect2, varscan2
- KCNN4 | c.409T>A p.S137T | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV53456589; called by muse, mutect2
- KCNV1 | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.9); PolyPhen benign (0.037); catalogued as COSV52086156; called by muse, mutect2, varscan2
- KCTD16 | c.1046G>A p.G349D | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as rs750531391, COSV72580154; called by muse, mutect2, varscan2
- KEL | c.560C>T p.S187F | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV62334102, COSV62336854; called by muse, mutect2, varscan2
- KHDRBS2 | c.638C>T p.P213L | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.521); catalogued as rs139228211; called by muse, mutect2, varscan2
- KIAA0232 | c.3406C>T p.P1136S | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.44); catalogued as rs373742606; called by muse, mutect2, varscan2
- KIAA1217 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV64610430; called by muse, mutect2, varscan2
- KIAA2026 | c.4825A>T p.K1609* | Nonsense Mutation (SNP) | VAF 14/53 reads (26%) | catalogued as COSV67356827; called by muse, mutect2, varscan2
- KIF13A | c.2734G>A p.V912M | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.017); catalogued as COSV52460792; called by muse, mutect2
- KIF19 | c.2894T>C p.V965A | Missense Mutation (SNP) | VAF 10/139 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV63430243; called by muse, mutect2
- KIF1A | c.2641G>A p.G881S | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs940784008, COSV57496860; called by muse, mutect2
- KIF21B | c.127G>A p.G43R | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100143152; called by muse, mutect2, varscan2
- KIF23 | c.2053C>T p.P685S | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.058); catalogued as COSV52981913; called by muse, mutect2, varscan2
- KIF2B | c.354G>A p.M118I | Missense Mutation (SNP) | VAF 28/194 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV52133828; called by muse, mutect2, varscan2
- KLF3 | c.38C>T p.A13V | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as COSV54711982; called by muse, mutect2, varscan2
- KLHL14 | c.1684G>A p.G562S | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV63834534; called by muse, mutect2, varscan2
- KLHL8 | c.1556C>T p.S519F | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV56748897; called by muse, mutect2, varscan2
- KMT2C | c.9853C>T p.Q3285* | Nonsense Mutation (SNP) | VAF 9/43 reads (21%) | catalogued as COSV51479702; called by muse, mutect2, varscan2
- KMT2D | c.6604C>T p.P2202S | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV56470767; called by muse, mutect2, varscan2
- KNDC1 | c.1285C>T p.P429S | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.83); PolyPhen benign (0.05); catalogued as COSV58841297; called by muse, mutect2
- KPRP | c.272C>T p.T91I | Missense Mutation (SNP) | VAF 39/194 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.257); catalogued as COSV100908628; called by muse, mutect2, varscan2
- KRT24 | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 43/134 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as rs752427510, COSV52881327; called by muse, mutect2, varscan2
- KRT26 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs761696509, COSV59412831; called by muse, mutect2, varscan2
- KRT38 | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV55847058; called by muse, mutect2, varscan2
- KRT6A | c.80G>A p.G27E | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as rs759307145, COSV58106799; called by muse, mutect2
- KRT71 | c.1060C>T p.L354F | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.084); catalogued as COSV57292263; called by muse, mutect2, varscan2
- KRT83 | c.1153C>T p.Q385* | Nonsense Mutation (SNP) | VAF 17/67 reads (25%) | catalogued as COSV53341752; called by muse, mutect2, varscan2
- KRTAP10-4 | c.14C>T p.S5F | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100551257; called by muse, varscan2
- KRTAP19-5 | c.208G>A p.G70R | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as rs73186218; called by muse, mutect2, varscan2
- KRTAP5-3 | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs571662260, COSV101294499, COSV68790920; called by muse, mutect2, varscan2
- L1TD1 | c.1522G>A p.E508K | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as COSV63133557, COSV63134025; called by muse, mutect2, varscan2
- LAD1 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.178); catalogued as COSV66213031; called by muse, mutect2, varscan2
- LAMA1 | c.5329G>A p.E1777K | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV67541572; called by muse, mutect2, varscan2
- LAYN | c.668T>A p.F223Y (on ENST00000375615 / NM_001258390.1; = p.F215Y on NM_178834.5) | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.139); catalogued as COSV65105260; called by muse, mutect2, varscan2
- LCN8 | c.292C>T p.P98S (on ENST00000612714 / NM_001345934.1; = p.P75S on NM_178469.3) | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV60210873; called by muse, mutect2, varscan2
- LCT | c.4432G>A p.D1478N | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.023); catalogued as rs1344262133, COSV51548121; called by muse, mutect2, varscan2
- LCT | c.2735C>T p.S912F | Missense Mutation (SNP) | VAF 52/87 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51545740; called by muse, mutect2, varscan2
- LDLRAD1 | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as COSV100744542, COSV62810098; called by muse, mutect2, varscan2
- LELP1 | c.254C>T p.S85F | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.158); catalogued as COSV64202542, COSV64202608; called by muse, mutect2, varscan2
- LGALS9C | c.997C>T p.R333C | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as rs769945043; called by muse, mutect2, varscan2
- LGR4 | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.243); catalogued as COSV64865597; called by muse, mutect2, varscan2
- LHFPL3 | c.260C>T p.P87L | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); catalogued as COSV67817162; called by muse, mutect2, varscan2
- LILRA4 | c.1415G>A p.R472K | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV52493863; called by muse, mutect2, varscan2
- LILRB5 | c.607C>T p.P203S | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); catalogued as COSV60256554; called by muse, mutect2, varscan2
- LMBR1L | c.1219C>T p.P407S | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as COSV57268612; called by muse, mutect2, varscan2
- LMCD1 | c.311C>T p.P104L | Missense Mutation (SNP) | VAF 57/223 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50090305; called by muse, mutect2, varscan2
- LMO7 | c.4459C>T p.P1487S (on ENST00000357063; = p.P1168S on NM_005358.5) | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.486); catalogued as rs749328214, COSV58543872; called by muse, mutect2, varscan2
- LPA | c.4029G>A p.W1343* | Nonsense Mutation (SNP) | VAF 25/70 reads (36%) | catalogued as COSV100308181, COSV60307240; called by muse, mutect2, varscan2
- LRCH2 | c.1949G>A p.R650Q | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious (0.02); PolyPhen benign (0.138); catalogued as rs1556526574, COSV57745620; called by muse, mutect2, varscan2
- LRIT2 | c.1612G>A p.E538K | Missense Mutation (SNP) | VAF 43/138 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV60565102; called by muse, mutect2, varscan2
- LRP1B | c.9644C>T p.P3215L | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs867247866, COSV67256017; called by muse, mutect2, varscan2
- LRP1B | c.8329C>T p.R2777* | Nonsense Mutation (SNP) | VAF 59/119 reads (50%) | catalogued as rs371528816, COSV67198045, COSV67229562; called by muse, mutect2, varscan2
- LRRC31 | c.862G>A p.D288N | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs1156481462, COSV52982208; called by muse, mutect2, varscan2
- LRRC37A3 | c.3683G>A p.G1228E | Missense Mutation (SNP) | VAF 50/158 reads (32%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.994); catalogued as rs749664094, COSV58536241; called by muse, mutect2, varscan2
- LRRIQ1 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV67813625; called by muse, mutect2, varscan2
- LRRN1 | c.1300C>T p.R434C | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.533); catalogued as rs1300200167, COSV60012895; called by muse, mutect2, varscan2
- LRRTM4 | c.239A>G p.Q80R | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101297670, COSV69139188; called by muse, mutect2, varscan2
- LUZP2 | c.824G>A p.G275E | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs267602831, COSV61199276; called by muse, mutect2, varscan2
- LY6G6F-LY6G6D | c.1018C>T p.P340S | Missense Mutation (SNP) | VAF 133/680 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as COSV65419985; called by muse, mutect2, varscan2
- LY6K | c.218-1G>A p.X73_splice | Splice Site (SNP) | VAF 12/30 reads (40%) | catalogued as rs1202250571, COSV52833311; called by muse, mutect2, varscan2
- LY75 | c.1790G>A p.C597Y | Missense Mutation (SNP) | VAF 77/124 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV55110801; called by muse, mutect2, varscan2
- LY86 | c.46C>T p.P16S | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.025); catalogued as COSV57913386; called by muse, mutect2, varscan2
- LYG2 | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60716275; called by muse, mutect2, varscan2
- MAGEA10 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 55/84 reads (65%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV54885180; called by muse, mutect2, varscan2
- MAGEA10 | c.250C>T p.P84S | Missense Mutation (SNP) | VAF 85/154 reads (55%) | SIFT tolerated (0.62); PolyPhen benign (0.07); catalogued as COSV54885194; called by muse, mutect2
- MAGEA10 | c.248C>T p.P83L | Missense Mutation (SNP) | VAF 84/151 reads (56%) | SIFT tolerated (0.39); PolyPhen benign (0.147); catalogued as COSV54885206; called by muse, mutect2
- MAGEB6 | c.181C>T p.P61S | Missense Mutation (SNP) | VAF 28/44 reads (64%) | SIFT tolerated (0.18); PolyPhen benign (0.117); catalogued as rs868530714, COSV66872666; called by muse, mutect2, varscan2
- MAGEE2 | c.1184G>A p.S395N | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV64898251; called by muse, mutect2, varscan2
- MAGI2 | c.1402G>A p.E468K | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.52); catalogued as COSV62636253; called by muse, mutect2, varscan2
- MAML3 | c.2860G>A p.G954R | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs200652438, COSV72209803; called by muse, mutect2, varscan2
- MAN1A1 | c.1475G>A p.G492D | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs761798893, COSV63788633; called by muse, mutect2, varscan2
- MAN1A2 | c.1654C>T p.Q552* | Nonsense Mutation (SNP) | VAF 16/68 reads (24%) | catalogued as COSV62978515; called by muse, mutect2, varscan2
- MAP3K1 | c.1748C>T p.A583V | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1034896455, COSV101265994; called by muse, mutect2, varscan2
- MAP3K21 | c.1165C>T p.P389S | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64045822; called by muse, mutect2, varscan2
- MAP3K9 | c.1357C>T p.R453W | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs752979159, COSV67122410; called by muse, mutect2, varscan2
- MAP4 | c.196C>T p.P66S | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.412); catalogued as COSV100805261; called by muse, mutect2, varscan2
- MARCHF10 | c.1024C>T p.H342Y | Missense Mutation (SNP) | VAF 129/214 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.129); catalogued as COSV60889563; called by muse, mutect2, varscan2
- MBD3L1 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.322); catalogued as COSV59776270; called by muse, mutect2, varscan2
- MCHR2 | c.996G>A p.M332I | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs767132068, COSV56006727; called by muse, mutect2, varscan2
- MEI1 | c.3134T>A p.L1045H | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55905715; called by muse, mutect2, varscan2
- MEN1 | c.1042G>A p.D348N | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.56); PolyPhen benign (0.065); catalogued as COSV99580013; called by muse, mutect2, varscan2
- MEP1A | c.1391G>A p.G464E | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57920307; called by muse, mutect2, varscan2
- METTL6 | c.508C>A p.L170I | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.038); catalogued as COSV67542464; called by muse, mutect2, varscan2
- MFAP1 | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.043); catalogued as COSV99979525; called by muse, mutect2, varscan2
- MICB | c.322G>A p.G108R | Missense Mutation (SNP) | VAF 12/15 reads (80%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.788); catalogued as rs748026188, COSV52857359; called by muse, mutect2, varscan2
- MIER1 | c.463T>G p.Y155D (on ENST00000355356 / NM_001077701.3; = p.Y172D on NM_020948.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.974); catalogued as COSV62531444; called by muse, mutect2
- MME | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV64709280; called by muse, mutect2, varscan2
- MMP27 | c.343A>T p.I115L | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.758); catalogued as COSV52782047; called by muse, mutect2, varscan2
- MMP3 | c.806C>T p.S269F | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as rs782821084, COSV55405152; called by muse, mutect2, varscan2
- MNDA | c.514C>T p.H172Y | Missense Mutation (SNP) | VAF 34/158 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0.045); catalogued as COSV63740672; called by muse, mutect2, varscan2
- MNDA | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751266784, COSV63740840; called by muse, mutect2, varscan2
- MOAP1 | c.559C>T p.H187Y | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV52093179; called by muse, mutect2, varscan2
- MOB3C | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.029); catalogued as COSV54718284, COSV54720074; called by muse, mutect2, varscan2
- MORN1 | c.1270G>A p.E424K | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.86); PolyPhen benign (0.025); catalogued as COSV66006672; called by muse, mutect2
- MPP6 | c.80G>A p.G27E | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); catalogued as COSV56041229; called by muse, varscan2
- MRC2 | c.3977G>A p.R1326Q | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.72); PolyPhen benign (0.284); catalogued as rs1434402229, COSV57642843; called by muse, mutect2
- MRNIP | c.368C>T p.T123I | Missense Mutation (SNP) | VAF 86/318 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.095); catalogued as COSV52974561; called by muse, mutect2, varscan2
- MROH8 | c.808C>T p.P270S | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.652); catalogued as COSV54122975; called by muse, mutect2, varscan2
- MSH3 | c.2314G>A p.G772R | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV54159184, COSV99434457; called by muse, mutect2, varscan2
- MTCL1 | c.3479G>A p.R1160Q (on ENST00000306329 / NM_001378206.1; = p.R841Q on NM_015210.4) | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.883); catalogued as rs376928119; called by muse, mutect2, varscan2
- MUC1 | c.3614C>T p.P1205L (on ENST00000611571 / NM_001371720.1; = p.P216L on NM_002456.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100103738; called by muse, mutect2, varscan2
- MUC1 | c.3613C>T p.P1205S (on ENST00000611571 / NM_001371720.1; = p.P216S on NM_002456.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.985); catalogued as rs1455615705, COSV58113907; called by muse, mutect2, varscan2
- MUC16 | c.29145G>A p.W9715* | Nonsense Mutation (SNP) | VAF 15/47 reads (32%) | catalogued as COSV67481938; called by muse, mutect2, varscan2
- MUC16 | c.21911C>T p.S7304F | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.26); catalogued as COSV67481941, COSV67497680; called by muse, mutect2, varscan2
- MUC16 | c.21199C>T p.P7067S | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.393); catalogued as rs1403709235, COSV67481945; called by muse, mutect2, varscan2
- MUC16 | c.18481C>T p.P6161S | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.01); catalogued as COSV67481950; called by muse, mutect2, varscan2
- MUC16 | c.10304G>A p.G3435E | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.033); catalogued as COSV67481954; called by muse, mutect2, varscan2
- MUC16 | c.9446C>T p.S3149L | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.765); catalogued as rs764972844, COSV67481957; called by muse, mutect2, varscan2
- MUC16 | c.7273G>A p.A2425T | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); catalogued as COSV67481961; called by muse, mutect2, varscan2
- MUC17 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 53/175 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV60281185; called by muse, mutect2, varscan2
- MUC17 | c.2938G>A p.E980K | Missense Mutation (SNP) | VAF 90/294 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as rs755553445, COSV60295091; called by muse, mutect2, varscan2
- MUC17 | c.7882C>T p.P2628S | Missense Mutation (SNP) | VAF 74/272 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.857); catalogued as COSV60296132; called by muse, mutect2, varscan2
- MUC17 | c.10829C>T p.S3610F | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV60289237, COSV60298147; called by muse, mutect2, varscan2
- MUCL1 | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.009); catalogued as COSV58193535; called by muse, mutect2
- MXRA5 | c.8318C>T p.S2773L | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.695); catalogued as rs1366305934, COSV54237231; called by muse, mutect2, varscan2
- MXRA5 | c.3406G>A p.V1136I | Missense Mutation (SNP) | VAF 29/46 reads (63%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as rs202161929, COSV54244490; called by muse, mutect2, varscan2
- MYCBP2 | c.1106G>A p.R369K (on ENST00000357337; = p.R407K on NM_015057.5) | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs1294482880, COSV62032090; called by muse, mutect2, varscan2
- MYCBPAP | c.1865C>T p.A622V | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as COSV60410295; called by muse, mutect2, varscan2
- MYH1 | c.1498G>A p.E500K | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV56854107; called by muse, mutect2, varscan2
- MYH2 | c.2574G>A p.M858I | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV55431764; called by muse, mutect2, varscan2
- MYH4 | c.1504G>A p.E502K | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV55117438; called by muse, mutect2, varscan2
- MYH7 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62522063; called by muse, mutect2, varscan2
- MYH8 | c.5323G>A p.E1775K | Missense Mutation (SNP) | VAF 41/152 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as rs753326378, COSV67967537; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO15A | c.4018G>A p.E1340K | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV52762178, COSV99234972; called by muse, mutect2, varscan2
- MYO18B | c.2056G>A p.G686S | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.943); catalogued as COSV59143427; called by muse, mutect2, varscan2
- MYO3A | c.4228G>A p.D1410N | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as COSV56319253, COSV56337583; called by muse, mutect2, varscan2
- MYO5C | c.2528G>A p.G843E | Missense Mutation (SNP) | VAF 48/184 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs1566975966, COSV55910306; called by muse, mutect2, varscan2
- MYO7A | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.303); catalogued as COSV68686287; called by muse, mutect2, varscan2
- MYO9B | c.1982C>T p.A661V | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68281721; called by muse, mutect2, varscan2
- MYOC | c.835C>T p.P279S | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV50674992; called by muse, mutect2, varscan2
- MYOCD | c.1292C>T p.P431L | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.221); catalogued as COSV58508868; called by muse, mutect2, varscan2
- MYOCD | c.1921G>A p.G641R | Missense Mutation (SNP) | VAF 48/153 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.209); catalogued as COSV58508882; called by muse, mutect2, varscan2
- MYOM3 | c.1337G>A p.R446Q | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377651260; called by muse, mutect2, varscan2
- MYPOP | c.1195C>T p.P399S | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.362); catalogued as COSV56194180; called by muse, mutect2, varscan2
- MYT1L | c.3233C>A p.S1078Y | Missense Mutation (SNP) | VAF 36/154 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.66); catalogued as COSV67704050; called by muse, varscan2
- NAALAD2 | c.1751C>T p.P584L | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58964323; called by muse, mutect2, varscan2
- NAP1L2 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 53/82 reads (65%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV65172871; called by muse, mutect2, varscan2
- NAV2 | c.2855C>T p.S952F (on ENST00000396087 / NM_001244963.2; = p.S929F on NM_145117.5) | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60663058; called by muse, mutect2
- NBAS | c.6530T>C p.V2177A | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV55732503; called by muse, mutect2, varscan2
- NBEA | c.158C>T p.S53L | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.039); catalogued as COSV59808870; called by muse, mutect2
- NCAM1 | c.346C>T p.Q116* | Nonsense Mutation (SNP) | VAF 21/32 reads (66%) | catalogued as rs539504433, COSV57515015; called by muse, mutect2, varscan2
- NCAM2 | c.2463del p.V823Ffs*23 | Frame Shift Del (DEL) | VAF 17/82 reads (21%) | catalogued as COSV99524454; called by mutect2, pindel, varscan2
- NCAPD3 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 11/46 reads (24%) | catalogued as rs774478261, COSV73258548; called by muse, mutect2, varscan2
- NCKAP5 | c.2342C>T p.S781L | Missense Mutation (SNP) | VAF 61/119 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.242); catalogued as rs1360305745, COSV58464064; called by muse, mutect2, varscan2
- NCKAP5 | c.1438G>A p.D480N | Missense Mutation (SNP) | VAF 65/108 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as rs758470126, COSV58443225; called by muse, mutect2, varscan2
- NDST4 | c.1414C>T p.P472S | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs866291626, COSV52109617; called by muse, mutect2, varscan2
- NDUFAF2 | c.193G>A p.G65R | Missense Mutation (SNP) | VAF 41/142 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV56942348; called by muse, mutect2, varscan2
- NECTIN2 | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.85); catalogued as COSV52979079; called by muse, mutect2, varscan2
- NEFH | c.1165C>A p.L389I | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as COSV60219450; called by muse, varscan2
- NEFL | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.284); catalogued as COSV55337990; called by muse, mutect2, varscan2
- NEK10 | c.2600G>A p.G867D | Missense Mutation (SNP) | VAF 40/151 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV55362908; called by muse, mutect2, varscan2
- NEXMIF | c.3734G>A p.G1245E | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT tolerated (0.85); PolyPhen benign (0.167); catalogued as COSV99279212; called by muse, mutect2, varscan2
- NF1 | c.1939C>T p.H647Y | Missense Mutation (SNP) | VAF 33/132 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as rs776251084, COSV62213849; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NHS | c.4826C>T p.S1609F | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66279760; called by muse, mutect2, varscan2
- NLN | c.853C>T p.P285S | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV66766744; called by muse, mutect2, varscan2
- NLRP1 | c.3499C>T p.P1167S | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV52563696; called by muse, mutect2
- NLRP10 | c.196G>A p.G66R | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV60781585; called by muse, mutect2, varscan2
- NLRP11 | c.2617G>A p.E873K | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.119); catalogued as COSV64086016, COSV64088386; called by muse, mutect2, varscan2
- NLRP3 | c.1272G>A p.M424I | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as COSV60229257; called by muse, mutect2, varscan2
- NLRP7 | c.369G>A p.W123* | Nonsense Mutation (SNP) | VAF 98/339 reads (29%) | catalogued as COSV60179036; called by muse, mutect2, varscan2
- NLRP8 | c.487C>T p.P163S | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.64); PolyPhen benign (0.013); catalogued as rs1373209788, COSV52591682; called by muse, mutect2, varscan2
- NME6 | c.160G>A p.E54K (on ENST00000415053; = p.E62K on NM_005793.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.467); catalogued as COSV56640891; called by muse, mutect2, varscan2
- NOCT | c.668C>T p.P223L | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757537642, COSV54936686; called by muse, mutect2, varscan2
- NOS1 | c.1490C>T p.T497I | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57618211; called by muse, mutect2, varscan2
- NOS1AP | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.038); catalogued as COSV62634327; called by muse, mutect2, varscan2
- NOTCH4 | c.1765G>A p.E589K | Missense Mutation (SNP) | VAF 99/456 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.505); catalogued as COSV66679287, COSV66682818; called by muse, mutect2, varscan2
- NOTCH4 | c.95C>T p.P32L | Missense Mutation (SNP) | VAF 66/313 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.082); catalogued as COSV66679876; called by muse, mutect2, varscan2
- NOVA2 | c.676C>T p.P226S | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54359109; called by muse, mutect2, varscan2
- NPAP1 | c.1328C>T p.P443L | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.133); catalogued as COSV61509780; called by muse, mutect2, varscan2
- NPAP1 | c.1583C>T p.S528F | Missense Mutation (SNP) | VAF 49/182 reads (27%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs865895928, COSV61506356; called by muse, mutect2, varscan2
- NPC1 | c.2884A>T p.I962F | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV52581760; called by muse, mutect2, varscan2
- NPC1L1 | c.3025C>T p.H1009Y | Missense Mutation (SNP) | VAF 37/153 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV56928573; called by muse, mutect2, varscan2
- NPHS2 | c.666G>A p.M222I | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.05); catalogued as rs1266101014, COSV62636106; called by muse, mutect2, varscan2
- NPR1 | c.1639G>A p.E547K | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.55); PolyPhen benign (0.425); catalogued as COSV64117928; called by muse, mutect2, varscan2
- NRN1 | c.100G>A p.V34I | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.103); catalogued as rs986669160, COSV55205584, COSV55206198; called by muse, mutect2, varscan2
- NRXN1 | c.1745G>A p.R582K | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV58478502; called by muse, mutect2, varscan2
- NRXN3 | c.2971G>A p.D991N (on ENST00000335750 / NM_001330195.2; = p.D618N on NM_004796.6) | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.991); catalogued as COSV59785961; called by muse, mutect2, varscan2
- NSUN2 | c.973C>T p.P325S | Missense Mutation (SNP) | VAF 45/82 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1460980954, COSV52956124; called by muse, mutect2, varscan2
- NTM | c.425C>T p.S142F | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV66186374, COSV66188318; called by muse, mutect2, varscan2
- NTNG1 | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53982464; called by muse, mutect2
- NUAK2 | c.1355C>T p.P452L | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.136); catalogued as COSV65681771; called by muse, mutect2
- NUP210 | c.3682G>A p.E1228K | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.891); catalogued as rs1026389606, COSV54403879; called by muse, mutect2
- NWD1 | c.565C>T p.L189F | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV60348156; called by muse, mutect2, varscan2
- NYAP2 | c.1954C>T p.R652C | Missense Mutation (SNP) | VAF 137/243 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.855); catalogued as rs767234499, COSV56010970, COSV56012840; called by muse, mutect2, varscan2
- OCIAD1 | c.323C>T p.S108F | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765644170, COSV51901916; called by muse, mutect2, varscan2
- ODAPH | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 56/166 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as rs1253765396, COSV61141291; called by muse, mutect2, varscan2
- OR10J3 | c.169C>T p.H57Y | Missense Mutation (SNP) | VAF 43/138 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.167); catalogued as COSV59954473; called by muse, mutect2, varscan2
- OR10K1 | c.467C>T p.S156F | Missense Mutation (SNP) | VAF 48/187 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV56873308; called by muse, mutect2, varscan2
- OR10P1 | c.109G>A p.V37I | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT tolerated (0.92); PolyPhen benign (0.007); catalogued as COSV59008184; called by muse, mutect2, varscan2
- OR10Q1 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57471451; called by muse, mutect2, varscan2
- OR11H6 | c.755G>A p.R252Q | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.074); catalogued as rs367798181; called by muse, mutect2, varscan2
- OR13C3 | c.668C>T p.S223F | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.359); catalogued as COSV66166109; called by muse, mutect2, varscan2
- OR13G1 | c.399G>A p.M133I | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as COSV62944935; called by muse, mutect2, varscan2
- OR13H1 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 35/56 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV58548167; called by muse, mutect2, varscan2
- OR13J1 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV65069581; called by muse, mutect2, varscan2
- OR14J1 | c.877G>A p.D293N | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as rs942553604, COSV65845875; called by muse, mutect2, varscan2
- OR1L8 | c.107A>G p.Y36C | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as COSV59186998; called by muse, mutect2, varscan2
- OR2F1 | c.415G>A p.G139R | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.084); catalogued as COSV67331815; called by muse, mutect2, varscan2
- OR2J2 | c.271A>T p.K91* | Nonsense Mutation (SNP) | VAF 44/191 reads (23%) | catalogued as COSV65848269; called by muse, mutect2, varscan2
- OR2T3 | c.137G>A p.G46E | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.178); catalogued as COSV100612982; called by muse, mutect2, varscan2
- OR2W1 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65851783; called by muse, varscan2
- OR4A15 | c.307C>T p.H103Y | Missense Mutation (SNP) | VAF 48/166 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.589); catalogued as rs775681810, COSV59036695; called by muse, mutect2, varscan2
- OR4C15 | c.998C>T p.P333L (on ENST00000314644; = p.P279L on NM_001001920.2) | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.881); catalogued as rs550535681, COSV58954607; called by muse, mutect2, varscan2
- OR4D11 | c.602C>T p.S201F | Missense Mutation (SNP) | VAF 36/134 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.988); catalogued as COSV57586641; called by muse, mutect2, varscan2
- OR4E2 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 56/198 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs369838154; called by muse, mutect2, varscan2
- OR4M1 | c.760G>A p.G254R | Missense Mutation (SNP) | VAF 30/325 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as rs1405180671, COSV60062819; called by muse, mutect2
- OR4N2 | c.503T>A p.F168Y | Missense Mutation (SNP) | VAF 36/350 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as COSV60053696; called by muse, varscan2
- OR4X1 | c.307C>T p.H103Y | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs377489408; called by muse, mutect2, varscan2
- OR51E1 | c.98C>A p.P33Q | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV67810642; called by muse, mutect2, varscan2
- OR51F1 | c.893C>T p.P298L | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58579080; called by muse, mutect2
- OR51F1 | c.409G>A p.D137N | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV58580358; called by muse, mutect2
- OR51F2 | c.904C>T p.Q302* | Nonsense Mutation (SNP) | VAF 27/107 reads (25%) | catalogued as rs1230451762, COSV59065588; called by muse, mutect2, varscan2
- OR51L1 | c.829C>T p.L277F | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as COSV104395551, COSV58625347; called by muse, mutect2
- OR51S1 | c.412C>T p.L138F | Missense Mutation (SNP) | VAF 38/141 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59059499; called by muse, mutect2, varscan2
- OR52A1 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.71); PolyPhen benign (0.009); catalogued as COSV61091903; called by muse, mutect2, varscan2
- OR52E4 | c.454G>A p.G152R | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as COSV57624430; called by muse, mutect2, varscan2
- OR56A4 | c.802C>T p.L268F | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.278); catalogued as rs1474585239, COSV58111285; called by muse, mutect2
- OR5AR1 | c.58G>A p.D20N | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT tolerated (0.93); PolyPhen benign (0.041); catalogued as rs773426823, COSV57253486, COSV57254777; called by muse, mutect2, varscan2
- OR5H2 | c.490C>T p.H164Y | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV62351498; called by muse, mutect2, varscan2
- OR5H6 | c.321G>A p.M107I (on ENST00000642105; = p.M91I on NM_001005479.2) | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs764734582, COSV67351016; called by muse, mutect2, varscan2
- OR5J2 | c.10G>A p.D4N | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV56622609; called by muse, mutect2, varscan2
- OR5K4 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 66/258 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs902873759, COSV61583677; called by muse, mutect2, varscan2
- OR5M8 | c.119G>A p.G40E | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.435); catalogued as COSV59115818; called by muse, mutect2, varscan2
- OR6F1 | c.500C>T p.S167F | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.845); catalogued as COSV57468908; called by muse, mutect2, varscan2
- OR6F1 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100128971, COSV57467462; called by muse, mutect2, varscan2
- OR7D4 | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV58072170; called by muse, mutect2, varscan2
- OR8B12 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as COSV60912389; called by muse, mutect2, varscan2
- OR9A4 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 49/152 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as COSV71885849; called by muse, mutect2, varscan2
- ORAI1 | c.878C>T p.P293L | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as COSV100345316; called by muse, mutect2, varscan2
- OSMR | c.405G>A p.W135* | Nonsense Mutation (SNP) | VAF 23/98 reads (23%) | catalogued as COSV57089524; called by muse, mutect2, varscan2
- OTOGL | c.982C>T p.P328S (on ENST00000547103; = p.P319S on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV72006458; called by muse, mutect2, varscan2
- OTOP3 | c.341C>T p.S114F | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV60914367; called by muse, mutect2, varscan2
- OTX1 | c.854C>T p.P285L | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as COSV56995619, COSV99246427; called by muse, mutect2, varscan2
- OXA1L | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.025); catalogued as rs866495733, COSV53537277; called by muse, mutect2, varscan2
- PACSIN1 | c.672G>A p.M224I | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV55061738; called by muse, mutect2, varscan2
- PALLD | c.2008G>A p.D670N | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as rs767729090, COSV54989537; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PALMD | c.989G>A p.R330Q | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.207); catalogued as rs556174782, COSV54163638; called by muse, mutect2, varscan2
- PAM | c.2291C>T p.S764F | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as rs1385984412, COSV57211717; called by muse, mutect2, varscan2
- PAPOLG | c.727C>T p.L243F | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.472); catalogued as COSV53184537; called by muse, mutect2, varscan2
- PAPPA | c.4447G>A p.E1483K | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs775634573, COSV60282314; called by muse, mutect2, varscan2
- PARL | c.1124G>A p.G375E | Missense Mutation (SNP) | VAF 52/222 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV57701695; called by muse, mutect2, varscan2
- PARP14 | c.751C>T p.P251S | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.815); catalogued as COSV71735323; called by muse, mutect2, varscan2
- PARP16 | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs374649627; called by muse, mutect2, varscan2
- PARP2 | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); catalogued as COSV51641186; called by muse, mutect2, varscan2
- PCCB | c.965C>T p.S322F | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.255); catalogued as COSV52447319; called by muse, mutect2, varscan2
- PCDH11X | c.3482C>T p.S1161F | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.219); catalogued as COSV53491814; called by muse, mutect2, varscan2
- PCDH15 | c.5060C>T p.P1687L (on ENST00000644397 / NM_001354429.2; = p.P1629L on NM_001142771.2) | Missense Mutation (SNP) | VAF 74/250 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.228); catalogued as COSV64719546; called by muse, mutect2, varscan2
- PCDH15 | c.2039G>A p.S680N | Missense Mutation (SNP) | VAF 66/270 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.241); catalogued as rs762818138, COSV57364536; called by muse, varscan2
- PCDHA1 | c.1325C>T p.S442F | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.398); catalogued as rs782327256, COSV65376069; called by muse, mutect2, varscan2
- PCDHA12 | c.646G>A p.D216N | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV56490077, COSV56498146; called by muse, mutect2, varscan2
- PCDHA12 | c.2065C>T p.P689S | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.003); catalogued as rs1413175649, COSV56532255; called by muse, mutect2, varscan2
- PCDHA3 | c.2066C>T p.P689L | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as rs564787047, COSV63544572; called by muse, mutect2, varscan2
- PCDHA7 | c.1600C>T p.Q534* | Nonsense Mutation (SNP) | VAF 39/184 reads (21%) | catalogued as rs1290587139, COSV65342137; called by muse, mutect2, varscan2
- PCDHA8 | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.653); catalogued as COSV65339198; called by muse, mutect2, varscan2
- PCDHA8 | c.2321C>T p.P774L | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV65330653; called by muse, mutect2, varscan2
- PCDHAC2 | c.1540C>T p.Q514* | Nonsense Mutation (SNP) | VAF 20/101 reads (20%) | catalogued as COSV53863036; called by muse, mutect2, varscan2
- PCDHB12 | c.114A>C p.E38D | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.955); catalogued as COSV53399414; called by muse, mutect2, varscan2
- PCDHB16 | c.1434A>T p.R478S | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.006); catalogued as COSV53368058; called by muse, mutect2, varscan2
- PCDHB4 | c.2108C>T p.S703L | Missense Mutation (SNP) | VAF 51/203 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.716); catalogued as COSV52025300; called by muse, mutect2, varscan2
- PCDHB8 | c.50C>T p.S17F | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as rs782235899, COSV50769178; called by muse, mutect2, varscan2
- PCDHB8 | c.1165G>A p.D389N | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.012); catalogued as COSV50798903; called by muse, mutect2, varscan2
- PCDHB8 | c.2326C>T p.Q776* | Nonsense Mutation (SNP) | VAF 21/87 reads (24%) | catalogued as COSV50798904, COSV50827022; called by muse, mutect2, varscan2
- PCLO | c.15052G>A p.E5018K | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV61655238; called by muse, mutect2, varscan2
- PCLO | c.9053G>A p.G3018E | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as rs267601591, COSV61655254, COSV99067669; called by muse, mutect2, varscan2
- PCNX3 | c.5174G>A p.R1725Q | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.835); catalogued as rs1260652833, COSV63139346; called by muse, mutect2, varscan2
- PCSK5 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.325); catalogued as COSV65093631; called by muse, mutect2, varscan2
- PCSK5 | c.4801C>T p.H1601Y | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101377212; called by muse, mutect2, varscan2
- PCSK6 | c.638C>T p.P213L | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59343474; called by muse, mutect2, varscan2
- PDE3A | c.2131C>T p.L711F | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62968336, COSV62979511, COSV62982795; called by muse, mutect2, varscan2
- PDE4D | c.1913T>A p.I638K (on ENST00000340635 / NM_001104631.2; = p.I502K on NM_006203.4) | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV57719688; called by muse, mutect2, varscan2
- PDHA2 | c.328G>A p.D110N | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54780887; called by muse, mutect2, varscan2
- PDPN | c.271C>T p.H91Y (on ENST00000621990; = p.H167Y on NM_006474.4) | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.925); catalogued as COSV53849751; called by muse, varscan2
- PDPN | c.314C>T p.A105V (on ENST00000621990; = p.A181V on NM_006474.4) | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.97); PolyPhen benign (0.08); catalogued as COSV53849762; called by muse, varscan2
- PDZD2 | c.1106G>A p.G369E | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1175962710, COSV56867684; called by muse, mutect2
- PDZRN3 | c.2462C>T p.T821I | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.03); catalogued as rs1345220367, COSV55195084, COSV55210633; called by muse, mutect2, varscan2
- PEAR1 | c.2024C>T p.P675L | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV52774910; called by muse, mutect2, varscan2
- PEG3 | c.578G>A p.R193Q | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as COSV55634565; called by muse, mutect2, varscan2
- PEX3 | c.766C>T p.R256* | Nonsense Mutation (SNP) | VAF 21/62 reads (34%) | catalogued as rs1227211727, COSV62569258; called by muse, mutect2, varscan2
- PGBD2 | c.352C>T p.R118C | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.328); catalogued as rs770910641, COSV61400768; called by muse, mutect2, varscan2
- PGM2 | c.1247G>A p.G416E | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as COSV101126522; called by muse, mutect2, varscan2
- PHF14 | c.2548G>A p.E850K | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV68856662; called by muse, mutect2, varscan2
- PHF2 | c.397G>A p.D133N | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.24); catalogued as COSV63682901; called by muse, mutect2, varscan2
- PHF20 | c.572C>T p.P191L | Missense Mutation (SNP) | VAF 49/115 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0.055); catalogued as rs774172000, COSV59187874; called by muse, mutect2, varscan2
- PHKA1 | c.1286G>A p.R429K | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV59809280; called by muse, mutect2, varscan2
- PHRF1 | c.1060C>T p.P354S | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs377699361; called by muse, mutect2, varscan2
- PIEZO2 | c.7976C>T p.P2659L | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV53292531; called by muse, mutect2, varscan2
- PIGR | c.2071G>A p.E691K | Missense Mutation (SNP) | VAF 29/128 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV62904718; called by muse, mutect2, varscan2
- PIK3AP1 | c.485C>T p.S162F | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.047); catalogued as rs779864167, COSV59535403; called by muse, mutect2, varscan2
- PIK3C2G | c.1939G>A p.E647K (on ENST00000676171; = p.E606K on NM_004570.5) | Missense Mutation (SNP) | VAF 45/141 reads (32%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.795); catalogued as COSV56803755, COSV56823957; called by muse, mutect2, varscan2
- PIK3CG | c.1945G>A p.E649K | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.056); catalogued as COSV63251770, COSV63254189; called by muse, mutect2, varscan2
- PIK3R3 | c.794C>T p.S265L | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.04); catalogued as COSV53110002; called by muse, mutect2, varscan2
- PITPNM3 | c.323G>A p.G108E | Missense Mutation (SNP) | VAF 42/135 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.216); catalogued as COSV52598444; called by muse, mutect2, varscan2
- PKD2L1 | c.1288T>C p.F430L | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.444); catalogued as COSV58397890; called by muse, mutect2, varscan2
- PKNOX1 | c.842A>C p.H281P | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52338516; called by muse, mutect2, varscan2
- PKP2 | c.1642G>A p.G548S | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.085); catalogued as COSV50740750; called by muse, mutect2, varscan2
- PLA2G3 | c.889C>T p.P297S | Missense Mutation (SNP) | VAF 34/148 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as COSV53211782; called by muse, mutect2, varscan2
- PLCB1 | c.97G>A p.D33N | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV62062001; called by muse, mutect2, varscan2
- PLCB4 | c.3317G>A p.R1106Q | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.885); catalogued as rs760014812, COSV53794833; called by muse, mutect2, varscan2
- PLCD4 | c.337C>T p.Q113* | Nonsense Mutation (SNP) | VAF 11/15 reads (73%) | catalogued as COSV101335798; called by muse, mutect2, varscan2
- PLCH1 | c.2468G>A p.G823E (on ENST00000340059 / NM_001130960.2; = p.G835E on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58206248; called by muse, mutect2, varscan2
- PLCH1 | c.1619G>A p.G540E (on ENST00000340059 / NM_001130960.2; = p.G552E on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as COSV58206272; called by muse, mutect2, varscan2
- PLCH2 | c.1460C>T p.S487F | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1236895837, COSV53947492; called by muse, mutect2, varscan2
- PLEKHA6 | c.1825-1G>A p.X609_splice | Splice Site (SNP) | VAF 6/22 reads (27%) | catalogued as COSV55338218; called by muse, mutect2, varscan2
- PLEKHA6 | c.1739C>T p.A580V | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.058); catalogued as COSV55338233; called by muse, mutect2, varscan2
- PLK2 | c.1955C>T p.S652F | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57107475, COSV57109137, COSV57110159; called by muse, mutect2, varscan2
- PLK3 | c.508C>T p.L170F | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV59500689; called by muse, mutect2, varscan2
- PLXNA4 | c.4588G>A p.E1530K | Missense Mutation (SNP) | VAF 66/272 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV58141285; called by muse, mutect2, varscan2
- PMS1 | c.1196C>T p.S399F | Missense Mutation (SNP) | VAF 45/77 reads (58%) | SIFT tolerated (0.15); PolyPhen benign (0.442); catalogued as COSV59716367; called by muse, mutect2, varscan2
- POF1B | c.1496T>C p.F499S | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.395); catalogued as COSV99425819; called by muse, mutect2, varscan2
- POLE | c.5060C>T p.S1687F | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57686724; called by muse, mutect2, varscan2
- POLR1H | c.52G>A p.D18N | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.058); catalogued as COSV60138601; called by muse, mutect2, varscan2
- POM121 | c.2837C>T p.P946L (on ENST00000434423; = p.P681L on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.629); catalogued as COSV57521488; called by mutect2, varscan2
877 further variants in this file (323 protein-altering or splice-affecting, 525 silent, 29 other) are not listed here.
